National Lung Screening Trial (NLST) participant 118791 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 15): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 30 mA, display field of view 28 cm, reconstruction filter Phillips C.
- T1 (day 398): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 60 mA, 36 effective mAs, display field of view 29 cm, reconstruction filter Phillips C.
- T2 (day 713): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 60 mA, 36 effective mAs, display field of view 31 cm, reconstruction filter Phillips C.

Abnormalities recorded by the reading radiologist on the CT screens (5 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T1 abnormality 1: Emphysema.
- T1 abnormality 2: Benign lung nodule(s) (benign calcification).
- T2 abnormality 1: Emphysema.
- T2 abnormality 2: Benign lung nodule(s) (benign calcification).
- T2 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,603.
